Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A8GL, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A8GL-06A (Metastatic).

[page 1 of 2]
*Case imported from . The format of this report does not
match the original case. For cases prior to the section
'SPECIMEN' may have been added.**

DIAGNOSIS:

- (A) RIGHT AXILLA, SKIN ELLIPSE:
MALIGNANT MELANOMA, METASTATIC TO SUBCUTANEOUS TISSUE, BIOPSIED.
Tumor size 1.2 x 1.0 cm (gross examination).
Borders of tumor pushing.
- (B) ADDITIONAL TISSUE, DEEP MARGIN:
Fibroadipose tissue. Melanoma not identified.
- (C) ADDITIONAL TISSUE:
Fibroadipose tissue. Melanoma not identified.
- (D) SUPERIOR MARGIN:
Fibroadipose tissue. Melanoma not identified.
- (E) ADDITIONAL MEDIAL MARGIN:
Fibroadipose tissue. Melanoma not identified.
- (F) RIGHT MEDIAL ARM, SKIN PUNCH:
Pityrosporum folliculitis.

ICD-O.3
Melanoma NOS 8720/3
Site: Sq. tissue, axilla
049.2
7/11/2 7/13

Entire report and diagnosis completed by:
Report released by:

GROSS DESCRIPTION:

- (A) MELANOMA, RIGHT AXILLA - A single, unoriented, 4.0 x 0.7 cm skin ellipse with 3.5 cm deep subcutaneous soft tissue.
Unremarkable, nodular, well circumscribed, mass with the largest measuring 1.2 x 1.0 x 0.6 cm in the subcutaneous soft tissue.
SECTION CODE: A1, largest nodule, bisected; A2, entire remaining nodules.
- (B) ADDITIONAL TISSUE, STITCH TRUE DEEP MARGIN, RIGHT AXILLA - A single, oriented, 4.5 x 3.0 x 1.0 cm light yellow fibroadipose tissue fragment. No distinct nodules are present.
INK CODE: Blue - true margin.
SECTION CODE: B1-B5, entire true margin, shaved and submitted en face.
- (C) ADDITIONAL TISSUE, STITCH TRUE MARGIN (NEW LOCATION IS IDENTIFIED ON THE SPECIMEN LABEL) - A single oriented, 1.8 x 1.2 x 0.6 cm light yellow tissue specimen.
INK CODE: Blue - true margin.
SECTION CODE: Entire specimen en face.
- (D) SUPERIOR MARGIN, STITCH TRUE MARGIN - A single, oriented, 1.5 x 1.3 x 0.5 cm soft tissue fragment.
INK CODE: Blue - true margin.

[page 2 of 2]
SECTION CODE: D, entire specimen.

(E) ADDITIONAL MEDIAL MARGIN, STITCH TRUE MARGIN - A single, oriented, 2.0 x 1.5 x 0.6 cm light yellow tissue fragment.

INK CODE: Blue - true margin.

SECTION CODE: E, entire specimen.

(F) PUNCH BIOPSY, RIGHT MEDIAL ARM - A skin punch biopsy (0.3 x 0.2 x 0.2 cm), entirely submitted in F.

SNOMED CODES:

M-87206 M-00564 T-02420 T-02630 T-D8100

10/28/13

Source: NCI Genomic Data Commons file 9070d1f5-e01d-4ac5-884e-3b36424530cd (TCGA-D3-A8GL.A0641060-FDDC-4DF0-BB13-9978B74F7D1A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).